Surgical pathology report (de-identified scan), TCGA case TCGA-99-8033, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Alabama, specimen TCGA-99-8033-01A (Primary Tumor).

Patient Name	MR#	Observation Date	Last Edited Date

SURGICAL PATHOLOGY

CASE:

Received Date:

Diagnosis

Lung, right upper lobe, wedge excision: - Poorly differentiated adenocarcinoma.- Lymphovascular invasion is present. - Margins negative for malignancy.

(Electronically signed by)

Verified:

Clinical Information

The patient is a year-old female.

Frozen Section Diagnosis

AFS1: Right upper lobe: - Non small cell carcinoma consistent with adenocarcinoma.

Gross Description

The specimen is received in a single container labeled with the patient's name, medical record number, and "#1 - wedge, right upper lobe." The specimen received fresh for frozen and now in formalin consists of a wedge of lung which measures 9.5 x 4.0 x 2.0 cm. There is a staple line margin along the length of the wedge. Sectioning of the lung reveals a well-defined round tan mass measuring 1.4 cm in greatest dimension. This mass is separated and is well away from the staple line margin grossly with the closest margin being approximately 1.0 cm away. Additionally, there is a frozen section in a orange cassette labeled A1. The remnant measures 2.0 x 1.0 x 0.3 cm and is resubmitted entirely.

Block Summary

- A1- Frozen remnant.
- A2- Section of mass.
- A3- Staple line margin nearest mass.
- A4- Representative section of normal appearing lung.
- A5- Additional section of tumor.

Microscopic Description

A microscopic examination has been performed.

Source: NCI Genomic Data Commons file d8cda51b-9349-4b2a-865a-62079ed01b16 (TCGA-99-8033.A7F10FD8-AB32-4ADB-94A9-31632E286B11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).